Somatic mutation profile of tumor specimen 0DHE02 from CCDI case PBBULB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Overlapping lesion of brain and central nervous system; Age at diagnosis: 4.8 years (1,764 days).
Specimen 0DHE02: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fddff7e9-ca02-4d25-92e1-5416bd61f664.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHDZD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b47cd6f-7239-45c9-88de-ed7fda86b789

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, Splice Region 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM83H | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 26/478 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs907890265; called by muse, mutect2
- IL17RD | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 70/278 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV56336109; called by muse, mutect2, varscan2
- KLK9 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 164/347 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs775609805; called by muse, mutect2, varscan2
- SENP3 | c.1454G>A p.R485H | Missense Mutation (SNP) | VAF 208/632 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.962); catalogued as rs371797427; called by muse, varscan2
- CSNK2A3 | c.982G>C p.V328L | Missense Mutation (SNP) | VAF 45/903 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- FKRP | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 172/333 reads (52%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- ODF2 | c.814G>C p.D272H (on ENST00000434106 / NM_153433.2; = p.D248H on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/602 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.009); called by muse, mutect2
- SBF2 | c.4257+3A>C | Splice Region (SNP) | VAF 32/176 reads (18%) | called by mutect2, varscan2
- ZNF578 | c.1653T>A p.H551Q | Missense Mutation (SNP) | VAF 124/438 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- AP3D1 | c.603G>A p.S201= | Silent (SNP) | VAF 83/406 reads (20%) | catalogued as rs1200577993; called by muse, mutect2, varscan2
- PLPPR4 | c.1254G>A p.P418= | Silent (SNP) | VAF 180/565 reads (32%) | catalogued as rs202142961, COSV64564643; called by muse, mutect2, varscan2
- MED13 | c.1010-14dup | Intron (INS) | VAF 54/309 reads (17%) | catalogued as rs753630500; called by mutect2, varscan2
- PLA2G1B | c.-12C>T | 5'UTR (SNP) | VAF 170/380 reads (45%) | called by muse, mutect2, varscan2
